TCGA case TCGA-DD-A4NL — Liver Hepatocellular Carcinoma (TCGA-LIHC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Liver and intrahepatic bile ducts; Tissue source site: Mayo Clinic - Rochester. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e0067280-2722-46f2-a5a8-352c77b47e38

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 46 years; Vital status: Alive.

Diagnoses (1)
1. Hepatocellular carcinoma, NOS: ICD-O-3 morphology code: 8170/3; ICD-10 code: C22.0; Tissue or organ of origin: Liver; Site of resection or biopsy: Liver; Classification of tumor: primary; Age at diagnosis: 46.2 years (16,874 days); Year of diagnosis: 2007; AJCC staging edition: 6th; AJCC pathologic T: T1; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; Tumor grade: G1; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 1,711 days (4.7 years); Ishak fibrosis score: 0 - No Fibrosis.
   Pathology details: Consistent pathology review: Yes; Vascular invasion present: No.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis.
   Recorded as not given: adjuvant Ablation or Embolization, NOS; adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 1,711 days (4.7 years); Disease response: Tumor Free.
- ECOG performance status: 1.

Molecular and laboratory tests
- Platelets 266 (unit not recorded by GDC) [Blood test normal range lower: 150; Blood test normal range upper: 450].
- Alpha Fetoprotein 2 ng/mL [Blood test normal range lower: 0; Blood test normal range upper: 6].
- Creatinine 1 mg/dL [Blood test normal range lower: 0.8; Blood test normal range upper: 1.3].
- Albumin 4.4 (unit not recorded on the TCGA source form) [Blood test normal range lower: 3.5; Blood test normal range upper: 5].
- Total Bilirubin 0.3 mg/dL [Blood test normal range lower: 0.1; Blood test normal range upper: 1].

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factors: Alcohol Consumption / Tobacco, NOS; Viral hepatitis serology tests: Hepatitis B Surface Antigen / HBV Surface Antibody / HBV Core Antibody.
- Timepoint category: Initial Diagnosis; Weight: 113 kg; Height: 173 cm; BMI: 37.8.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DD-A4NL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 80 mg.
  Slide TCGA-DD-A4NL-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-DD-A4NL-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DD-A4NL-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 140 mg.
  Slide TCGA-DD-A4NL-11A-01-TS1: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Histologic diagnosis: Hepatocellular Carcinoma; Definitive surgical procedure: Segmentectomy, Single; New tumor event diagnosis indicator: No.
- Viral hepatitis serologies: Viral hepatitis serology: Hepatitis B Surface Antigen; Viral hepatitis serology: HBV Surface Antibody; Viral hepatitis serology: HBV Core Antibody.
- Follow-up form 1: Lost to follow-up: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Follow-up form 2: Lost to follow-up: Yes; Tumor status: Tumor free; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,711 days; disease-specific survival: no event (censored), 1,711 days; disease-free interval: no event (censored), 1,711 days; progression-free interval: no event (censored), 1,711 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DD-A4NL-01A-11D-A28W-01): tumor purity 0.5, ploidy 2, whole-genome doublings 0.
